Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A3YB, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A3YB-01A (Primary Tumor).

Path Report: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Esophagus Distal per TSS

Tumor size: 2.7 x 2 x 1.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 1/3 positive for metastasis (Intraabdominal 1/3)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

Carcinoma, Squamous cell, NOS
807013

Site-

CQCF- Esophagus, distal third
C15.5

Path- esophagus, NOS

C15.9

6/12/12

RD

W 5/24/12

Source: NCI Genomic Data Commons file 6c0554af-a880-4f8b-b7dc-a7c03b29a944 (TCGA-IG-A3YB.3886C17E-7195-49AD-BD16-3317A4A5AD20.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).